Gene-level copy-number profile of tumor specimen C3L-06227-04 from CPTAC case C3L-06227, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 62.6 years (22,880 days).
Specimen C3L-06227-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b21e5c0d-6104-4273-ac66-c869ee8df4c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06227-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/bf3f8223-6475-42ed-b479-088d688625fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 6,071; copy number 2: 42,307; copy number 3: 6,992; copy number 4: 782; copy number 5: 2,712.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:95,836,919–95,991,831, 1 gene: ANKRD36C.
- chr4:91,603,275–91,605,292, 1 gene: AC110774.1.
- chr5:117,415,509–117,546,298, 1 gene: LINC00992.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:49,960,249–49,969,625, 2 genes: DEFB114, DEFB113.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,712 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–57,837,046, 1,033 genes, copy number 5 (broad region; genes not listed).
- chr7:63,011,463–97,599,260, 625 genes, copy number 5 (broad region; genes not listed).
- chr7:102,748,971–131,754,252, 450 genes, copy number 5 (broad region; genes not listed).
- chr7:132,784,870–159,233,377, 597 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–18,596,310, 7 genes, copy number 5 (within-gene range 2–5): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13.

Autosomal genes at a single copy (total copy number 1): 3,265. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
